Somatic mutation profile of tumor specimen TCGA-76-6280-01A (aliquot TCGA-76-6280-01A-21D-1845-08) from TCGA case TCGA-76-6280, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,931 days).
Specimen TCGA-76-6280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ae882d7-d9da-4a19-833d-b5673a8a6046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6280-10A (Blood Derived Normal), aliquot TCGA-76-6280-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4bdefab-e3fd-4b5d-be2e-051c4f648673

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 2, In Frame Ins 1, Intron 1, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1402_1410dup p.E468_Y470dup (on ENST00000521381 / NM_181523.3; = p.E198_Y200dup on NM_181504.4) | In Frame Ins (INS) | VAF 24/49 reads (49%) | hotspot (GDC flag); called by mutect2, varscan2
- AANAT | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs72466447, COSV51684175; called by mutect2, varscan2
- ADNP2 | c.501C>G p.Y167* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV51537662; called by muse, mutect2, varscan2
- CACNA1B | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV53121383; called by muse, mutect2, varscan2
- CASP10 | c.1349G>A p.R450Q (on ENST00000272879 / NM_032974.5; = p.R407Q on NM_001230.5) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949451411, COSV53777514; called by muse, mutect2, varscan2
- CD22 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.402); catalogued as rs779809517, COSV50051240; called by muse, mutect2, varscan2
- CEL | c.961G>A p.A321T (on ENST00000673714; = p.A318T on NM_001807.6) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs769996201, COSV60829568; called by mutect2, varscan2
- CFAP20DC | c.664C>T p.R222C (on ENST00000482387 / NM_001351530.2; = p.R97C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs773017513, COSV55918449; called by muse, mutect2, varscan2
- COG6 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62995500, COSV62995628; called by muse, mutect2, varscan2
- COQ8B | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54686495; called by muse, mutect2, varscan2
- DCAF5 | c.2732G>A p.R911K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV58459685; called by muse, mutect2, varscan2
- HIP1R | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772173203, COSV53440780; called by muse, mutect2
- IGF2R | c.6127G>A p.A2043T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV63627930; called by muse, mutect2, varscan2
- KCNE3 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59551724; called by muse, mutect2, varscan2
- KIF2B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370597263; called by muse, mutect2, varscan2
- MAP2K3 | c.116+1G>A p.X39_splice (on ENST00000342679 / NM_145109.3; = p.X10_splice on NM_002756.4) | Splice Site (SNP) | VAF 33/196 reads (17%) | catalogued as rs368105298, COSV57575118; called by muse, mutect2, varscan2
- MROH2B | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV68182500; called by muse, mutect2, varscan2
- NAV2 | c.3235G>A p.A1079T (on ENST00000396087 / NM_001244963.2; = p.A1056T on NM_145117.5) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV60658270; called by muse, mutect2, varscan2
- NDST4 | c.1220T>C p.L407P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.516); catalogued as COSV52115162; called by muse, mutect2, varscan2
- NFATC2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1337673442, COSV65353029; called by muse, mutect2, varscan2
- NIN | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752155088, COSV55386372, COSV99814310; called by muse, mutect2, varscan2
- OR52N1 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57693023, COSV57693175; called by muse, mutect2, varscan2
- OR5K4 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1024135691, COSV61583609, COSV61583793; called by muse, mutect2, varscan2
- PKHD1 | c.11740C>T p.R3914* | Nonsense Mutation (SNP) | VAF 75/158 reads (47%) | catalogued as rs761704401, COSV64381678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs747975201, COSV61869460; called by muse, mutect2, varscan2
- PLXNA2 | c.1961A>C p.Y654S | Missense Mutation (SNP) | VAF 150/426 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV65439657; called by muse, mutect2, varscan2
- PLXND1 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1362474229, COSV60711652; called by muse, mutect2, varscan2
- PRPF40A | c.2828A>G p.D943G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.418); catalogued as rs369227878; called by muse, mutect2, varscan2
- ROBO2 | c.2453C>A p.T818N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV59905722; called by muse, mutect2, varscan2
- RPS21 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV54156352, COSV54158648; called by muse, mutect2
- SPTAN1 | c.5593C>T p.R1865W | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1423165476, COSV63986385; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYT16 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747375303, COSV70856031; called by muse, mutect2, varscan2
- TJP3 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs146857520; called by muse, mutect2, varscan2
- TMEM132E | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs748511938, COSV58696071; called by muse, mutect2, varscan2
- TNFRSF19 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs748111366, COSV50312427; called by muse, mutect2, varscan2
- TRIM71 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV67470597; called by muse, varscan2
- ZPBP | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs200427468; called by muse, mutect2, varscan2
- ZNF700 | c.1149_1150del p.T385Wfs*6 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- ACTA2 | c.246C>T p.D82= | Silent (SNP) | VAF 57/86 reads (66%) | catalogued as rs1254836237, CM114010, COSV56516099; called by muse, mutect2, varscan2
- ATP2C2 | c.612C>A p.I204= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV52294467; called by muse, mutect2, varscan2
- CACNB2 | c.1503T>C p.D501= (on ENST00000324631 / NM_201596.3; = p.D446= on NM_000724.4) | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV56618919; called by muse, mutect2, varscan2
- CILP2 | c.2778C>G p.L926= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV52273989, COSV99364466; called by muse, mutect2, varscan2
- EHD4 | c.1407C>T p.N469= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs201800565, COSV55003288; called by muse, mutect2, varscan2
- GRM8 | c.1536G>A p.P512= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as rs774632571, COSV58809093, COSV58817276, COSV58852761; called by muse, mutect2, varscan2
- MAPT | c.1437G>A p.L479= (on ENST00000262410 / NM_001377265.1; = p.L404= on NM_016835.4) | Silent (SNP) | VAF 97/283 reads (34%) | catalogued as COSV52238898; called by muse, mutect2, varscan2
- MMP15 | c.1776C>T p.G592= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs761863348, COSV54679317; called by muse, mutect2, varscan2
- RAC3 | c.327C>T p.P109= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60711091; called by muse, mutect2, varscan2
- RNF40 | c.2715C>A p.L905= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV61214334; called by muse, mutect2, varscan2
- TM7SF2 | c.759C>T p.D253= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as rs763712793, COSV54206782; called by muse, mutect2, varscan2
- TRPV2 | c.324G>A p.S108= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs750738911, COSV58427935, COSV58430666; called by muse, mutect2, varscan2
- AC245884.12 | n.27C>T | RNA (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+1914G>A | Intron (SNP) | VAF 90/242 reads (37%) | catalogued as rs201738067, COSV100000511; called by muse, mutect2, varscan2
